Gene-level copy-number profile of tumor specimen TCGA-BC-A216-01A from TCGA case TCGA-BC-A216, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 62.9 years (22,968 days).
Specimen TCGA-BC-A216-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.f8406d7e-fe7f-48b8-9aab-5ffa57864129.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BC-A216-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/ebd2b9de-5b12-489d-aed2-8ecd30f58d2f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 4,761; copy number 2: 46,427; copy number 3: 5,300; copy number 4: 1,752; copy number 5: 1,457; copy number 6: 72; copy number 7: 19.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BC-A216-01A-11D-A151-01): tumor purity 0.84, ploidy 2.09, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:87,863,625–87,971,930, 1 gene (within-gene range 0–1): PTEN.
- chr10:87,945,502–88,259,372, 4 genes: RPL11P3, AC063965.1, MED6P1, AL353149.1.
- chr18:39,206,917–39,800,322, 8 genes (within-gene range 0–1): MIR924HG, AC011139.1, RPL7AP66, MIR924, AC099845.1, MIR5583-2, MIR5583-1, RNU6-1242P.
- chr18:50,795,120–51,085,045, 8 genes: MRO, HNRNPA3P16, RPL17P46, ME2, Y_RNA, ELAC1, AC091551.1, SMAD4.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,548 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:58,882,868–59,296,491, 7 genes, copy number 5: LINC02777, LINC01358, PHBP3, AL592431.2, AL592431.1, HSD52, AC093424.1.
- chr1:93,992,834–94,145,619, 2 genes, copy number 5: ABCA4, AC093579.1.
- chr1:94,150,738–94,151,080, 1 gene, copy number 5: RN7SL440P.
- chr1:167,529,117–168,263,481, 19 genes, copy number 7: CREG1, AL031733.1, AL031733.2, RCSD1, MPZL1, ADCY10, Z99943.2, Z99943.1, MPC2, DCAF6, MIR1255B2, GCSHP5, GPR161, TIPRL, RPL34P1, AL021397.1, SFT2D2, ANKRD36BP1, RNU6-1310P.
- chr1:179,025,804–245,709,432, 1,291 genes, copy number 5–6 (broad region; genes not listed).
- chr1:246,509,038–247,640,854, 54 genes, copy number 5 (within-gene range 4–5): AL356583.1, LINC01743, AL356583.3, AL356583.2, TFB2M, CNST, AL591623.1, AL591623.2, AL591848.2, AL591848.1, SCCPDH, RPL35AP6, KIF28P, AL591848.3, LINC01341, AC113174.1, AC113174.2, AHCTF1, ZNF695, ZNF670-ZNF695, AL512637.2, ZNF670, AL512637.1, AL627095.1, ZNF669, AL627095.2, C1orf229, FGFR3P6, ZNF124, AL390728.3, AL390728.2, AL390728.6, AL390728.4, MIR3916, RNA5SP82, AL390728.5, AL390728.1, VN1R17P, VN1R5, Y_RNA, ZNF496, AC104335.1, AC104335.2, NLRP3, OR2B11, OR2W5, GCSAML, OR2C3, GCSAML-AS1, AL606804.1, OR2G2, OR2G3, U6, OR14L1P.
- chr1:248,174,821–248,919,946, 41 genes, copy number 5: OR2M2, OR2M3, OR2M4, OR2T33, OR2T12, OR2M7, OR14C36, OR2T4, OR2T6, OR2T1, OR2T7, OR2T2, OR2T3, AC138089.1, OR2T5, OR2AS2P, OR2G6, AC098483.1, OR2AS1P, OR2T29, OR2T34, OR2T10, Y_RNA, AC098483.2, OR2T11, OR2T35, OR2T27, CR589904.2, OR14I1, LYPD9P, CR589904.1, AHCYP8, LYPD8, DPY19L4P1, SH3BP5L, MIR3124, ZNF672, ZNF692, AL672291.1, PGBD2, RNU6-1205P.
- chr2:46,392,291–46,670,778, 12 genes, copy number 5: LINC01820, LINC02583, AC016912.2, AC016912.1, RN7SL817P, TMEM247, ATP6V1E2, RHOQ, RHOQ-AS1, PIGF, CRIPT, AC020604.1.
- chr2:46,698,952–46,780,245, 1 gene, copy number 5 (within-gene range 3–5): SOCS5.
- chr3:71,675,414–72,279,503, 14 genes, copy number 5 (within-gene range 2–5): EIF4E3, GPR27, PROK2, AC096970.1, RN7SL271P, LINC00877, UBE2Q2P9, AC105265.2, AC105265.3, AC105265.1, CCDC137P, LINC00870, AC112219.2, AC112219.1.
- chr6:43,427,366–43,450,427, 1 gene, copy number 6 (within-gene range 2–6): ABCC10.
- chr6:43,450,352–44,074,652, 25 genes, copy number 6 (within-gene range 2–6): DLK2, RNU6-1113P, TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, AL157371.2, LINC02537, AL157371.1, AL109615.3, C6orf223.
- chr7:23,235,967–23,311,729, 2 genes, copy number 5 (within-gene range 2–5): GPNMB, MALSU1.
- chr9:35,161,992–36,487,548, 60 genes, copy number 5: UNC13B, AL160274.1, ATP8B5P, ZFAND6P1, RUSC2, AL133476.1, RPL36AP33, FAM166B, RPS29P17, AL357874.3, TESK1, MIR4667, CD72, AL357874.2, AL357874.1, SIT1, RMRP, RMRP, CCDC107, ARHGEF39, RN7SL22P, CA9, TPM2, TLN1, MIR6852, CREB3, MIR6853, GBA2, RGP1, MSMP, AL133410.2, AL133410.1, NPR2, SPAG8, HINT2, AL133410.3, TMEM8B, FAM221B, OR13E1P, OR13J1, NDUFA5P4, HRCT1, SPAAR, AL135841.1, PGAM1P2, OR2S2, OR2S1P, YBX1P10, OR13C6P, OR13C7, OR2AM1P, RECK, AL138834.1, GLIPR2, CCIN, CLTA, GNE, RNU4-53P, HMGB3P24, RNF38.
- chr10:32,887,273–33,917,804, 18 genes, copy number 5: ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1, AL353600.2, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629.

Autosomal genes at a single copy (total copy number 1): 4,721. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
